Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3728, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3728-01A (Primary Tumor).

Diagnosis:

Partial colon/rectum resection material shows two colorectal carcinomas:

An ulcerated carcinoma of the rectum characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 3 cm of the aboral resection margin and measuring 3.5 cm at its widest diameter. Invasive tumor spread within all layers of the intestinal wall as far as the periproctical fatty tissue.

2.: A carcinoma of the colon characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 4 cm of the oral resection margin and measuring 2 cm at its widest diameter. Invasive tumor spread as far as the level of the muscularis propria.

Oral and aboral resection margin tumor-free.

Three of nineteen periproctical or mesocolic lymph nodes with metastases of the rectum or colon carcinoma extending in some cases over the lymph node capsule.

Tumor stage of the rectum carcinoma thus pT3; G2

that of the colon carcinoma pT2; G3

Lymph node status pN1 (3/19) L0 V0

Source: NCI Genomic Data Commons file 87f2528f-325a-460d-8ba6-52e8f484dc31 (TCGA-AG-3728.1488DE24-4E80-412A-9E20-2B9B0DE38354.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).